Somatic mutation profile of tumor specimen TCGA-EJ-5532-01A (aliquot TCGA-EJ-5532-01A-01D-1576-08) from TCGA case TCGA-EJ-5532, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.8 years (21,110 days).
Specimen TCGA-EJ-5532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62c57d7e-9696-404a-b0ac-e60a01420c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5532-10A (Blood Derived Normal), aliquot TCGA-EJ-5532-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41e5b133-32be-4d76-a2bc-65db583c48b6

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 15, Silent 8, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN1 | c.740C>G p.T247S | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.969); catalogued as COSV56070911; called by muse, mutect2, varscan2
- CACNA2D4 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.987); catalogued as rs766593449, COSV54947762; called by muse, mutect2, varscan2
- CAD | c.3676G>A p.V1226I | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as rs746219339, COSV53024388; called by muse, mutect2, varscan2
- DMBT1 | c.3055G>A p.D1019N (on ENST00000338354 / NM_001377530.1; = p.D520N on NM_004406.3) | Missense Mutation (SNP) | VAF 229/601 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs773492969, COSV57545842; called by muse, mutect2, varscan2
- FBN1 | c.5999G>T p.C2000F | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM077270, CM161858, COSV57318648; called by muse, varscan2
- GZMA | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374808018; called by muse, mutect2, varscan2
- MYO1F | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375221696; called by muse, mutect2, varscan2
- OR4C13 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.139); catalogued as COSV73648770; called by muse, mutect2, varscan2
- PPARGC1B | c.850A>T p.M284L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58529750, COSV58533930; called by muse, mutect2, varscan2
- PRSS58 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73488683; called by muse, mutect2, varscan2
- SPTA1 | c.2859C>G p.D953E | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV63752879, COSV63754237; called by muse, mutect2
- ST6GALNAC2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 89/276 reads (32%) | PolyPhen probably damaging (0.998); catalogued as COSV56571498; called by muse, mutect2, varscan2
- UQCRC1 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs919564809, COSV52551933; called by muse, mutect2, varscan2
- USH2A | c.3932C>T p.S1311L | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs79279902, CM080597, COSV56361403; called by muse, mutect2, varscan2
- WNT2 | c.741C>G p.N247K | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV55411389; called by muse, varscan2
- CCDC144A | c.1308del p.M437Wfs*4 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- FLG2 | c.847_851del p.S283Ffs*18 | Frame Shift Del (DEL) | VAF 72/333 reads (22%) | called by mutect2, pindel, varscan2
- PUM1 | c.3456del p.K1153Sfs*17 | Frame Shift Del (DEL) | VAF 53/226 reads (23%) | called by mutect2, pindel, varscan2
- FCGBP | c.6633C>T p.C2211= | Silent (SNP) | VAF 44/283 reads (16%) | catalogued as rs778169511; called by muse, mutect2, varscan2
- MTUS2 | c.1749G>A p.T583= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs757126872, COSV70917100; called by muse, mutect2, varscan2
- MYO7A | c.762G>A p.V254= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV68684947; called by muse, mutect2, varscan2
- NAA25 | c.597T>C p.Y199= | Silent (SNP) | VAF 9/194 reads (5%) | catalogued as COSV55704690; called by muse, mutect2
- NKAPL | c.378G>A p.E126= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV59198089; called by muse, mutect2, varscan2
- SLC26A2 | c.1365T>A p.L455= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV53825429; called by muse, mutect2, varscan2
- USP22 | c.1269C>T p.T423= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV54947050; called by muse, mutect2, varscan2
- VWF | c.1488G>A p.E496= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV54622290; called by muse, mutect2, varscan2
